Somatic mutation profile of tumor specimen 17cd2121-d347-431c-9cc7-fbab14 (aliquot 17cd2121-d347-431c-9cc7-fbab14_D6) from CPTAC case 05CO050, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen 17cd2121-d347-431c-9cc7-fbab14: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20998ab5-4408-4c1e-8353-88cf2d42b1de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 757d441d-5ff7-409b-8578-3ba7b3 (Blood Derived Normal), aliquot 757d441d-5ff7-409b-8578-3ba7b3_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/211d55fe-94ba-49ed-9a82-d2d833bae9b7

The open-access MAF lists 2,975 somatic variants for this specimen: 1,960 protein-altering or splice-affecting, 611 silent, 404 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,345, Silent 611, Frame Shift Del 357, Intron 210, Frame Shift Ins 80, Nonsense Mutation 74, 3'UTR 66, Splice Site 54, RNA 40, 5'UTR 38, Splice Region 36, 5'Flank 30.

Variants (750 of 2,975; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3286C>T p.Q1096* | Nonsense Mutation (SNP) | VAF 86/395 reads (22%) | catalogued as rs587783029, CM995163, COSV57336639; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 72/318 reads (23%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BCAT2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749866079, CM159648; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CAPN3 | c.1795del p.T599Pfs*63 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as rs80338803; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- CDKN2A | c.151-1G>T p.X51_splice | Splice Site (SNP) | VAF 53/214 reads (25%) | hotspot (GDC flag); catalogued as rs730881677, CS014428, CS067079, COSV58682903, COSV58695350, COSV58708670, COSV58717973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- CPAMD8 | c.2352dup p.R785Qfs*23 (on ENST00000651564; = p.R738Qfs*23 on NM_015692.5) | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- INS | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 38/756 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs28933985, CM850007, CM920374, CM970784; ClinVar: pathogenic; called by muse, mutect2
- KCNQ2 | c.1678C>T p.R560W (on ENST00000359125 / NM_172107.4; = p.R532W on NM_004518.6) | Missense Mutation (SNP) | VAF 105/385 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773171451, CM120574; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KDM3B | c.4549C>T p.R1517* | Nonsense Mutation (SNP) | VAF 50/169 reads (30%) | catalogued as rs1554131871, COSV58690616; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 94/366 reads (26%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MECP2 | c.710del p.G237Vfs*11 | Frame Shift Del (DEL) | VAF 34/194 reads (18%) | catalogued as rs61749743, CD001509, CM076289; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.741del p.K247Nfs*32 | Frame Shift Del (DEL) | VAF 49/214 reads (23%) | catalogued as rs267608041; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 46/206 reads (22%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- OTC | c.613A>G p.M205V | Missense Mutation (SNP) | VAF 80/384 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as rs72558411, CM003036, COSV50001837; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PALB2 | c.3420G>A p.W1140* | Nonsense Mutation (SNP) | VAF 46/200 reads (23%) | catalogued as rs878855118; ClinVar: pathogenic; called by muse, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 27/97 reads (28%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 93/243 reads (38%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PXDN | c.2568del p.C857Afs*5 | Frame Shift Del (DEL) | VAF 75/261 reads (29%) | catalogued as rs558163499, CD117085; ClinVar: pathogenic; called by mutect2, varscan2
- RAD50 | c.1201A>T p.R401* | Nonsense Mutation (SNP) | VAF 44/170 reads (26%) | catalogued as rs199867309; ClinVar: pathogenic; called by muse, varscan2
- RPE65 | c.1067del p.N356Mfs*17 | Frame Shift Del (DEL) | VAF 66/293 reads (23%) | catalogued as rs281865520, CD972436; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- TAX1BP3 | c.233T>C p.M78T | Missense Mutation (SNP) | VAF 104/303 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs1307997067; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770958760; called by muse, varscan2
- ABCC1 | c.1642G>A p.V548M | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as COSV104414937; called by muse, mutect2, varscan2
- ABCC2 | c.3914A>G p.Y1305C | Missense Mutation (SNP) | VAF 126/517 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs747354567; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 26/56 reads (46%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCG4 | c.851T>C p.V284A | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV56644140; called by muse, mutect2, varscan2
- ABL2 | c.2768T>A p.L923H (on ENST00000502732 / NM_007314.4; = p.L908H on NM_005158.5) | Missense Mutation (SNP) | VAF 120/559 reads (21%) | SIFT tolerated, low confidence (0.48); PolyPhen possibly damaging (0.781); catalogued as rs1167820209; called by muse, mutect2, varscan2
- ABLIM3 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as COSV100448066; called by muse, mutect2, varscan2
- ACACB | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs561181524, COSV58144353; called by muse, mutect2, varscan2
- ACACB | c.3674G>A p.R1225Q | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs762060491, COSV58139483; called by muse, mutect2, varscan2
- ACKR4 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 127/488 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs543522851; called by muse, mutect2, varscan2
- ACSBG2 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 124/424 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs549601872, COSV99397689; called by mutect2, varscan2
- ACTL7B | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.482); catalogued as COSV65926868; called by muse, mutect2, varscan2
- ACTN4 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs753213013, COSV53145933; called by muse, mutect2, varscan2
- ACTRT1 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 153/558 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64418990; called by muse, mutect2, varscan2
- ADA2 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 77/251 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1390593004, COSV99375682; called by muse, mutect2, varscan2
- ADAD1 | c.244del p.I82Yfs*6 | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | catalogued as rs746068816; called by mutect2, varscan2
- ADAM11 | c.104del p.G35Afs*52 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs767694891; called by mutect2, varscan2
- ADAM18 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1281021669; called by muse, mutect2, varscan2
- ADAM23 | c.2340del p.K781Rfs*14 | Frame Shift Del (DEL) | VAF 22/129 reads (17%) | catalogued as rs767549806; called by mutect2, pindel, varscan2
- ADAMTS5 | c.1816T>G p.C606G | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753945495; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 122/555 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs745675169, COSV65892023; called by muse, mutect2, varscan2
- ADARB2 | c.1327C>T p.H443Y | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs142949222; called by muse, mutect2, varscan2
- ADGB | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100828259; called by muse, mutect2, varscan2
- ADGRA2 | c.3257del p.P1086Lfs*217 | Frame Shift Del (DEL) | VAF 41/154 reads (27%) | catalogued as rs1189742043; called by mutect2, pindel, varscan2
- ADGRL2 | c.2885C>T p.A962V (on ENST00000370717 / NM_001366005.1; = p.A949V on NM_012302.4) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs1026402375; called by muse, mutect2, varscan2
- ADGRL3 | c.296G>A p.R99H (on ENST00000506720 / NM_001322402.2; = p.R31H on NM_015236.6) | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764433793, COSV72265444, COSV72273929; called by muse, mutect2, varscan2
- ADIRF | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs201187335; called by muse, mutect2, varscan2
- ADRA2C | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 81/345 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1416092497; called by muse, mutect2, varscan2
- AEBP1 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as rs141003956; called by muse, mutect2, varscan2
- AEBP1 | c.2383del p.E795Rfs*32 | Frame Shift Del (DEL) | VAF 84/352 reads (24%) | catalogued as COSV56260153; called by mutect2, varscan2
- AFG1L | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs185227588, COSV64554670; called by muse, mutect2, varscan2
- AGAP2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as rs1182818492; called by muse, mutect2, varscan2
- AGAP6 | c.1634G>A p.R545H (on ENST00000374056 / NM_001365867.1; = p.R568H on NM_001077665.2) | Missense Mutation (SNP) | VAF 194/810 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs533152789, COSV100929051; called by muse, mutect2
- AHRR | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772512231, COSV57083815; called by muse, mutect2, varscan2
- AKR1B1 | c.430-1G>T p.X144_splice | Splice Site (SNP) | VAF 98/488 reads (20%) | catalogued as COSV53648696; called by muse, mutect2, varscan2
- AL117348.2 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 105/352 reads (30%) | PolyPhen benign (0); catalogued as rs145906534, COSV55282574; called by muse, mutect2, varscan2
- ALDH16A1 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745940024; called by mutect2, varscan2
- ALPK1 | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 88/476 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs777634886; called by muse, mutect2, varscan2
- AMER3 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs554983410; called by muse, mutect2, varscan2
- ANKAR | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1313349476, COSV55615349; called by muse, mutect2, varscan2
- ANKFY1 | c.2110G>A p.A704T (on ENST00000341657 / NM_001330063.2; = p.A705T on NM_016376.5) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs1442615858, COSV58915465; called by muse, mutect2, varscan2
- ANKK1 | c.1096del p.L366Sfs*13 | Frame Shift Del (DEL) | VAF 95/432 reads (22%) | catalogued as rs755428982; called by mutect2, varscan2
- ANKRD13C | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV52034857; called by muse, mutect2, varscan2
- ANKRD2 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV53968284; called by muse, mutect2, varscan2
- ANKRD20A1 | c.2087A>G p.Q696R | Missense Mutation (SNP) | VAF 61/546 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1263736759; called by muse, mutect2, varscan2
- ANO8 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251523199, COSV99344459; called by muse, mutect2, varscan2
- AP4B1 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 66/305 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298309914; called by muse, mutect2, varscan2
- APBB1 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 60/259 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs766381978, COSV54975389; called by muse, mutect2, varscan2
- APC | c.3014C>T p.A1005V | Missense Mutation (SNP) | VAF 115/479 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs876660427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APCDD1L | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100954022; called by mutect2, varscan2
- APOBEC3H | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs1372676517, COSV62378515; called by muse, mutect2
- AQP3 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 118/407 reads (29%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.589); catalogued as COSV53048420; called by muse, mutect2, varscan2
- AREL1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as rs910393595; called by muse, mutect2, varscan2
- ARGFX | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as rs548796906, COSV57681504; called by muse, mutect2
- ARHGAP23 | c.265del p.R89Gfs*15 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as rs1166703552; called by mutect2, pindel, varscan2
- ARHGAP23 | c.1343C>T p.T448I | Missense Mutation (SNP) | VAF 98/401 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs1365861850; called by muse, mutect2, varscan2
- ARHGAP5 | c.576dup p.P193Tfs*8 | Frame Shift Ins (INS) | VAF 24/130 reads (18%) | catalogued as rs1269856893; called by mutect2, varscan2
- ARHGEF5 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1245900888; called by mutect2, varscan2
- ARID1A | c.2812G>A p.A938T | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.703); catalogued as COSV61378739; called by muse, mutect2, varscan2
- ARID2 | c.2776G>A p.V926I | Missense Mutation (SNP) | VAF 34/391 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.452); catalogued as rs766416912, COSV57595243, COSV57608635, COSV57611015; called by muse, mutect2
- ARMH2 | c.136del p.I46Sfs*20 | Frame Shift Del (DEL) | VAF 54/212 reads (25%) | catalogued as rs965020534; called by mutect2, varscan2
- ARTN | c.429G>C p.E143D (on ENST00000372354; = p.E151D on NM_057090.2) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs762302784; called by muse, mutect2, varscan2
- ASXL3 | c.6110del p.P2037Hfs*43 | Frame Shift Del (DEL) | VAF 34/158 reads (22%) | catalogued as rs747712363; called by mutect2, varscan2
- ATP1A2 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 104/419 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM082492, COSV63403044; called by muse, mutect2, varscan2
- ATP6V0A2 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs754043585, CD093112, COSV57750859; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 26/99 reads (26%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- B4GALNT4 | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV57323370; called by muse, mutect2, varscan2
- B4GALNT4 | c.2972dup p.E992* | Frame Shift Ins (INS) | VAF 58/251 reads (23%) | catalogued as rs35951843; called by mutect2, varscan2
- BAG5 | c.974del p.N325Tfs*12 | Frame Shift Del (DEL) | VAF 77/310 reads (25%) | catalogued as rs1002009532; called by mutect2, pindel, varscan2
- BAHCC1 | c.4812del p.R1605Afs*107 | Frame Shift Del (DEL) | VAF 56/241 reads (23%) | catalogued as rs1555657301, COSV57027984; called by mutect2, pindel, varscan2
- BAIAP2L1 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs752773992; called by muse, mutect2, varscan2
- BCHE | c.1027del p.T343Pfs*16 | Frame Shift Del (DEL) | VAF 20/138 reads (14%) | catalogued as CM025285, COSV52257903; called by mutect2, pindel, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as rs752427670; called by mutect2, varscan2
- BET1L | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV57315401; called by muse, mutect2, varscan2
- BICD1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99861971; called by muse, mutect2
- BICRA | c.2810dup p.P938Tfs*127 | Frame Shift Ins (INS) | VAF 48/92 reads (52%) | catalogued as rs755506199; called by mutect2, varscan2
- BMPER | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 83/390 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs759114763; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 93/204 reads (46%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BMS1 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs745427494, COSV65735518; called by muse, mutect2, varscan2
- BNC1 | c.2259G>T p.E753D | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV61758073; called by muse, mutect2, varscan2
- BRIP1 | c.1505A>G p.E502G | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99369053; called by muse, mutect2, varscan2
- BRPF1 | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 86/384 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as rs753525669; called by muse, mutect2, varscan2
- BSN | c.7513dup p.L2505Pfs*13 | Frame Shift Ins (INS) | VAF 76/348 reads (22%) | catalogued as rs754418611; called by mutect2, varscan2
- BTBD11 | c.139T>C p.Y47H | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372703778; called by muse, mutect2, varscan2
- BTBD3 | c.1070A>G p.K357R | Missense Mutation (SNP) | VAF 67/379 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.81); catalogued as rs1418222465; called by muse, mutect2, varscan2
- C14orf180 | c.135del p.S46Pfs*3 | Frame Shift Del (DEL) | VAF 52/245 reads (21%) | catalogued as rs761345073; called by mutect2, pindel, varscan2
- C19orf71 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 153/520 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV61535723; called by muse, varscan2
- C1orf127 | c.2359del p.A787Pfs*7 | Frame Shift Del (DEL) | VAF 89/187 reads (48%) | catalogued as rs1283160262; called by mutect2, pindel, varscan2
- C2CD2L | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.91); catalogued as COSV60884785; called by muse, mutect2, varscan2
- CACNA1H | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs780596901; called by muse, mutect2, varscan2
- CACNA1H | c.3154G>T p.E1052* | Nonsense Mutation (SNP) | VAF 28/241 reads (12%) | catalogued as rs759989625; called by muse, mutect2, varscan2
- CACNA1I | c.6016C>T p.L2006F | Missense Mutation (SNP) | VAF 91/365 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1177475678; called by muse, mutect2, varscan2
- CALHM2 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1306164523; called by muse, mutect2, varscan2
- CARMIL2 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1260441386; called by muse, mutect2, varscan2
- CARS2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV57286295; called by muse, mutect2, varscan2
- CASKIN2 | c.1016del p.P339Rfs*95 | Frame Shift Del (DEL) | VAF 23/168 reads (14%) | catalogued as COSV100050703; called by mutect2, pindel, varscan2
- CASZ1 | c.4672G>A p.A1558T | Missense Mutation (SNP) | VAF 123/439 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.379); catalogued as rs760174926, COSV65456220; called by muse, mutect2, varscan2
- CASZ1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs760076051; called by muse, mutect2, varscan2
- CBR1 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs762808256; called by muse, mutect2, varscan2
- CCDC138 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs896059293, COSV54567061; called by muse, varscan2
- CCDC168 | c.16139G>A p.G5380D | Missense Mutation (SNP) | VAF 93/435 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as rs1191258345; called by muse, mutect2, varscan2
- CCDC168 | c.12457C>T p.Q4153* | Nonsense Mutation (SNP) | VAF 65/274 reads (24%) | catalogued as COSV59424931; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC40 | c.2911G>A p.V971I | Missense Mutation (SNP) | VAF 111/458 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746632559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC42 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 21/110 reads (19%) | catalogued as rs1285551885, COSV99549927; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC54 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs762728121, COSV53758412; called by muse, mutect2, varscan2
- CCDC62 | c.2036dup p.N679Kfs*51 | Frame Shift Ins (INS) | VAF 12/61 reads (20%) | catalogued as rs1053262354; called by mutect2, varscan2
- CCDC66 | c.619dup p.T207Nfs*2 (on ENST00000394672 / NM_001353147.1; = p.T173Nfs*2 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 34/159 reads (21%) | catalogued as rs1247408644; called by mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 72/292 reads (25%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC88B | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs746401310; called by muse, mutect2, varscan2
- CCN6 | c.624del p.K208Nfs*24 | Frame Shift Del (DEL) | VAF 36/153 reads (24%) | catalogued as rs781790231; called by mutect2, varscan2
- CCNA1 | c.236del p.P79Rfs*6 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | catalogued as COSV55219864; called by mutect2, pindel, varscan2
- CCND1 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as rs770991095, COSV57119629; called by muse, varscan2
- CCR3 | c.540G>C p.E180D | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV62466143; called by muse, mutect2, varscan2
- CD2 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs151304988; called by muse, mutect2, varscan2
- CD4 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs782135554, COSV50591503; called by muse, mutect2, varscan2
- CDH10 | c.1577del p.F526Sfs*3 | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | catalogued as rs1209448007; called by mutect2, varscan2
- CDH11 | c.998del p.K333Sfs*3 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs1208977261; called by mutect2, pindel, varscan2
- CDH12 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs745634405; called by muse, mutect2, varscan2
- CDH24 | c.714dup p.L239Afs*67 | Frame Shift Ins (INS) | VAF 75/256 reads (29%) | catalogued as rs765496989; called by mutect2, varscan2
- CDH5 | c.2057C>T p.A686V | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as rs543410829, COSV58519277; called by muse, mutect2, varscan2
- CDHR5 | c.1955C>T p.S652L (on ENST00000358353 / NM_001171968.2; = p.S658L on NM_021924.5) | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs752747793, COSV57645867; called by muse, mutect2, varscan2
- CDIPT | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as COSV104376445; called by muse, mutect2, varscan2
- CDK11A | c.2023C>T p.R675C (on ENST00000378633 / NM_001313896.2; = p.R672C on NM_024011.4) | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769472924, COSV99319156; called by muse, mutect2, varscan2
- CDK12 | c.2350C>T p.R784* | Nonsense Mutation (SNP) | VAF 23/108 reads (21%) | catalogued as COSV71002558; called by muse, varscan2
- CDKL2 | c.222del p.K74Nfs*5 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | catalogued as rs753353408; called by mutect2, varscan2
- CDON | c.2566A>G p.N856D | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs868554549; called by muse, mutect2, varscan2
- CDYL2 | c.354del p.Y120Ifs*27 | Frame Shift Del (DEL) | VAF 65/284 reads (23%) | catalogued as COSV101629564; called by mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 15/55 reads (27%) | catalogued as rs375852685; called by mutect2, varscan2
- CELSR1 | c.5544del p.T1849Rfs*8 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | catalogued as rs776824429; called by mutect2, pindel, varscan2
- CEP170B | c.3998C>T p.T1333M (on ENST00000453495; = p.T1262M on NM_015005.3) | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs1253916484; called by muse, mutect2, varscan2
- CEP295NL | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373812601; called by muse, mutect2, varscan2
- CEP85L | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs139462904; called by muse, mutect2, varscan2
- CERCAM | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1270318608; called by muse, mutect2, varscan2
- CFAP91 | c.1828C>T p.R610* | Nonsense Mutation (SNP) | VAF 31/150 reads (21%) | catalogued as rs747028037, COSV56341021; called by muse, mutect2, varscan2
- CH25H | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 44/536 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100897404, COSV64092338; called by muse, mutect2
- CHAF1A | c.1444C>T p.R482W | Missense Mutation (SNP) | VAF 110/400 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs755737623; called by muse, mutect2, varscan2
- CHD6 | c.4759G>A p.G1587S | Missense Mutation (SNP) | VAF 90/344 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1391945124, COSV64691533; called by muse, mutect2, varscan2
- CHODL | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 97/445 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs745697776, COSV100167177; called by muse, varscan2
- CHRD | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as rs772056992, COSV52609180; called by muse, mutect2, varscan2
- CHRNE | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 77/330 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.435); catalogued as rs575920043, COSV53418538; called by muse, mutect2, varscan2
- CHST2 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); catalogued as rs1167634143; called by muse, mutect2, varscan2
- CIAO2A | c.47T>G p.L16R | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs373353175, COSV55538849; called by muse, mutect2, varscan2
- CKMT1B | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs748158602; called by muse, mutect2, varscan2
- CLDN5 | c.59del p.G20Vfs*2 (on ENST00000618236 / NM_001363066.2; = p.G105Vfs*2 on NM_003277.4) | Frame Shift Del (DEL) | VAF 34/172 reads (20%) | catalogued as rs768198935; called by mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 18/124 reads (15%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPTM1 | c.1830del p.V611Wfs*147 | Frame Shift Del (DEL) | VAF 79/328 reads (24%) | catalogued as COSV61611992; called by mutect2, pindel, varscan2
- CLSPN | c.3415C>T p.R1139* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as rs1344308365, COSV52051490; called by muse, mutect2, varscan2
- CLUH | c.842C>A p.S281Y (on ENST00000435359; = p.S319Y on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV70929461; called by mutect2, varscan2
- CNOT1 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1011658922, COSV100410437, COSV57768261; called by muse, mutect2, varscan2
- CNST | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 86/374 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63619704; called by muse, mutect2, varscan2
- CNTN2 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59349823; called by muse, mutect2, varscan2
- CNTN6 | c.1708C>T p.H570Y | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV100609714; called by muse, mutect2, varscan2
- CNTNAP5 | c.340G>T p.G114* | Nonsense Mutation (SNP) | VAF 42/171 reads (25%) | catalogued as COSV70473796; called by muse, mutect2, varscan2
- COL18A1 | c.2491C>T p.P831S (on ENST00000359759 / NM_130444.3; = p.P596S on NM_030582.4) | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs1427546723; called by muse, mutect2, varscan2
- COL18A1 | c.4558C>T p.R1520W (on ENST00000359759 / NM_130444.3; = p.R1285W on NM_030582.4) | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs566518554; called by muse, mutect2, varscan2
- COL3A1 | c.2186G>T p.G729V | Missense Mutation (SNP) | VAF 117/402 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1412593, COSV100482879; called by muse, mutect2, varscan2
- COL5A1 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 89/390 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as rs148548209, COSV65669151; ClinVar: uncertain significance; called by mutect2, varscan2
- COL5A3 | c.3143del p.P1048Lfs*96 | Frame Shift Del (DEL) | VAF 18/108 reads (17%) | catalogued as rs771976753; called by mutect2, pindel, varscan2
- COQ8A | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 83/324 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs762900727, COSV62023325; ClinVar: uncertain significance; called by muse, mutect2
- CORO1A | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 157/517 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54631607; called by muse, varscan2
- CORO7-PAM16 | c.2806G>A p.V936M | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); catalogued as rs779163926, COSV52109375; called by muse, mutect2, varscan2
- COX15 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.599); catalogued as rs1251650006; called by muse, mutect2, varscan2
- CPE | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs202048102; called by muse, mutect2, varscan2
- CPNE1 | c.1463G>A p.R488Q (on ENST00000352393; = p.R493Q on NM_003915.5) | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs759648669; called by muse, mutect2, varscan2
- CPNE2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1181634754; called by muse, mutect2, varscan2
- CPNE7 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs766533546; called by muse, mutect2, varscan2
- CR2 | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 95/422 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs759229627; called by muse, mutect2, varscan2
- CREB3L1 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs775343544; called by muse, mutect2, varscan2
- CREBBP | c.5147C>T p.T1716M | Missense Mutation (SNP) | VAF 78/310 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52118838; called by mutect2, varscan2
- CRYAB | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs370803064, CM082584, COSV57052494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD2 | c.2632C>T p.R878C | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53971764; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 51/232 reads (22%) | catalogued as rs766438669; called by mutect2, varscan2
- CSMD3 | c.8675A>C p.N2892T (on ENST00000297405 / NM_001363185.1; = p.N2723T on NM_052900.3) | Missense Mutation (SNP) | VAF 69/321 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV99852475; called by muse, mutect2, varscan2
- CTNND2 | c.1124A>G p.H375R | Missense Mutation (SNP) | VAF 73/259 reads (28%) | SIFT tolerated (0.88); PolyPhen benign (0.038); catalogued as rs760758906; called by muse, mutect2, varscan2
- CTSL | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV58247499; called by muse, mutect2, varscan2
- CUL9 | c.6031C>T p.R2011C | Missense Mutation (SNP) | VAF 54/342 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); catalogued as rs747856369, COSV99335856; called by muse, mutect2, varscan2
- CXorf66 | c.1028T>A p.I343N | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV65169051; called by muse, mutect2, varscan2
- CYLC2 | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV66336288; called by muse, mutect2, varscan2
- CYP21A2 | c.601del p.T201Pfs*12 | Frame Shift Del (DEL) | VAF 267/990 reads (27%) | catalogued as CM1111385; called by mutect2, varscan2
- CYP2S1 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs762153062, COSV59507469; called by muse, mutect2, varscan2
- CYP7B1 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 134/674 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1410531135, COSV59584668, COSV59594434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP7B1 | c.319A>G p.K107E | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1370086356; called by muse, mutect2, varscan2
- CYTH2 | c.839G>A p.R280H (on ENST00000427476; = p.R279H on NM_004228.7) | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.188); catalogued as COSV57309065; called by muse, mutect2, varscan2
- DAB1 | c.37del p.T13Pfs*19 | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | catalogued as COSV59727279; called by mutect2, pindel, varscan2
- DAB2IP | c.3002G>A p.R1001H (on ENST00000408936; = p.R973H on NM_032552.3) | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1211930144, COSV52265295; called by muse, mutect2, varscan2
- DACH1 | c.674del p.G225Afs*9 | Frame Shift Del (DEL) | VAF 17/136 reads (13%) | catalogued as COSV57492753; called by mutect2, pindel, varscan2
- DAPK1 | c.4078G>A p.A1360T | Missense Mutation (SNP) | VAF 78/321 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.05); catalogued as rs747094261; called by muse, mutect2, varscan2
- DCAF1 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs373234360; called by muse, mutect2, varscan2
- DCAF10 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 56/205 reads (27%) | catalogued as rs948125986, COSV54289339; called by muse, mutect2, varscan2
- DCP1B | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 111/448 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs747504838, COSV54967141; called by muse, mutect2, varscan2
- DCT | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 68/355 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs760282974; called by muse, mutect2, varscan2
- DCTN1 | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 140/569 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs768409522; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDC | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 89/655 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs766408460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDN | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs763177634; called by muse, mutect2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX60 | c.3398del p.L1133Yfs*4 | Frame Shift Del (DEL) | VAF 22/107 reads (21%) | catalogued as rs778036194; called by mutect2, varscan2
- DEFB132 | c.127dup p.E43Gfs*24 | Frame Shift Ins (INS) | VAF 64/271 reads (24%) | catalogued as rs776618282; called by mutect2, pindel, varscan2
- DELE1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs997600066, COSV99519703; called by muse, mutect2, varscan2
- DGKZ | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs769790583, COSV100551082; called by muse, mutect2, varscan2
- DGKZ | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.543); catalogued as rs933466388; called by muse, mutect2, varscan2
- DHCR7 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 148/641 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765707139; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHRS7C | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV57650387; called by muse, mutect2, varscan2
- DLAT | c.723del p.V242Wfs*5 | Frame Shift Del (DEL) | VAF 74/275 reads (27%) | catalogued as rs782029228, COSV54771743; called by mutect2, varscan2
- DLG5 | c.5642G>A p.S1881N | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as rs751368828; called by muse, mutect2, varscan2
- DLG5 | c.5240C>A p.P1747H | Missense Mutation (SNP) | VAF 62/304 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64947095; called by muse, mutect2, varscan2
- DLGAP3 | c.2041del p.V681Cfs*95 | Frame Shift Del (DEL) | VAF 62/255 reads (24%) | catalogued as COSV52391941; called by mutect2, pindel, varscan2
- DLST | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs775945691, COSV53165956; called by muse, mutect2, varscan2
- DLX4 | c.319G>A p.E107K (on ENST00000240306 / NM_138281.3; = p.E35K on NM_001934.3) | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs752997759, COSV53593093, COSV99537815; called by muse, mutect2, varscan2
- DMD | c.6778T>G p.L2260V | Missense Mutation (SNP) | VAF 89/413 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.372); catalogued as COSV100627717; called by muse, mutect2, varscan2
- DMWD | c.1366dup p.L456Pfs*236 | Frame Shift Ins (INS) | VAF 20/92 reads (22%) | catalogued as rs746317972; called by mutect2, varscan2
- DNAH6 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs552271150; called by muse, mutect2, varscan2
- DNAH7 | c.2120A>G p.Y707C | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs751874043; called by muse, mutect2, varscan2
- DNAH9 | c.8071T>G p.F2691V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1041695768, COSV99305469; called by muse, mutect2, varscan2
- DNAH9 | c.9668A>G p.D3223G | Missense Mutation (SNP) | VAF 148/608 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs767823546; called by muse, mutect2, varscan2
- DNHD1 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 99/399 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54438497; called by muse, mutect2, varscan2
- DNHD1 | c.3994C>T p.Q1332* | Nonsense Mutation (SNP) | VAF 110/482 reads (23%) | catalogued as COSV54445265; called by muse, mutect2, varscan2
- DNLZ | c.369-2A>C p.X123_splice | Splice Site (SNP) | VAF 25/74 reads (34%) | catalogued as rs1385647877; called by muse, mutect2, varscan2
- DNPEP | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 86/341 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs569695061, COSV56110537; called by muse, mutect2, varscan2
- DOCK11 | c.2540G>T p.G847V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as rs946923564; called by muse, mutect2, varscan2
- DOK6 | c.343A>G p.R115G | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1287978912; called by muse, mutect2, varscan2
- DOT1L | c.3971C>T p.A1324V | Missense Mutation (SNP) | VAF 55/270 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.374); catalogued as rs748004837, COSV67111227; called by muse, mutect2, varscan2
- DRD2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 75/352 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753530257; called by muse, mutect2, varscan2
- DTNA | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 36/339 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145425478; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DTX2 | c.1381G>A p.G461S | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.371); catalogued as rs774439426; called by muse, mutect2
- DUOX1 | c.4568del p.P1523Lfs*3 | Frame Shift Del (DEL) | VAF 29/168 reads (17%) | catalogued as rs751561010; called by mutect2, pindel, varscan2
- DUSP10 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV60456636; called by muse, mutect2, varscan2
- DYRK1B | c.1633del p.Q545Sfs*19 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | catalogued as rs775499198; called by mutect2, pindel, varscan2
- DYRK2 | c.1427T>C p.V476A (on ENST00000344096 / NM_006482.3; = p.V403A on NM_003583.4) | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs780826338; called by muse, mutect2, varscan2
- EAPP | c.26A>G p.D9G | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1180284441; called by muse, mutect2, varscan2
- EBF1 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as rs1330428171; called by muse, mutect2, varscan2
- EBF3 | c.1385G>A p.R462H (on ENST00000355311 / NM_001375392.1; = p.R453H on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs775333110, COSV100799179; called by muse, varscan2
- EBF3 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62472103, COSV62473057; called by muse, mutect2, varscan2
- ECE2 | c.256A>G p.R86G | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1483385409, COSV100668895; called by muse, mutect2
- EDEM1 | c.196del p.V66Yfs*108 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs753811182; called by mutect2, pindel
- EIF5B | c.149del p.K50Sfs*10 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | catalogued as rs749961066, COSV56813566; called by mutect2, varscan2
- ELFN2 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.607); catalogued as rs367945618; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 50/104 reads (48%) | catalogued as rs766700925; called by mutect2, varscan2
- EML2 | c.82del p.A28Pfs*63 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs997582141; called by mutect2, pindel, varscan2
- EMX1 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 89/397 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99252379; called by muse, mutect2, varscan2
- EN2 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 65/304 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1229931747; called by muse, mutect2, varscan2
- ENC1 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 138/504 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs867274465, COSV56630362; called by muse, mutect2, varscan2
- EPB41 | c.1744del p.T582Qfs*11 (on ENST00000343067 / NM_001166005.2; = p.T373Qfs*11 on NM_004437.4) | Frame Shift Del (DEL) | VAF 68/296 reads (23%) | catalogued as COSV58042400; called by mutect2, pindel, varscan2
- EPG5 | c.3265C>A p.L1089I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV56352714; called by muse, mutect2, varscan2
- EPPK1 | c.6458C>T p.T2153M | Missense Mutation (SNP) | VAF 124/462 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.349); catalogued as rs201994568, COSV73262096; called by muse, mutect2, varscan2
- ERV3-1 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.468); catalogued as rs566324998, COSV51426735; called by muse, mutect2, varscan2
- EVC2 | c.1478T>C p.V493A | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs202210260; ClinVar: likely benign; called by muse, mutect2, varscan2
- EYA2 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs1404385933, COSV57938829; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 84/333 reads (25%) | catalogued as rs766589051; called by mutect2, varscan2
- FAM107B | c.-122-5del | Splice Region (DEL) | VAF 26/70 reads (37%) | catalogued as rs756478120; called by mutect2, varscan2
- FAM149A | c.69del p.A24Qfs*180 | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | catalogued as rs1438345086; called by mutect2, pindel
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 38/120 reads (32%) | catalogued as rs746881923; called by mutect2, varscan2
- FAM219A | c.492del p.K165Sfs*3 (on ENST00000445726; = p.K148Sfs*3 on NM_147202.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 38/132 reads (29%) | catalogued as rs760074479; called by mutect2, varscan2
- FAM47B | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.931); catalogued as rs1206961838; called by muse, mutect2, varscan2
- FAM71A | c.327del p.K109Nfs*8 | Frame Shift Del (DEL) | VAF 86/428 reads (20%) | catalogued as rs749381759; called by mutect2, pindel, varscan2
- FAM71E1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); catalogued as rs1400932703; called by muse, mutect2, varscan2
- FAM83B | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373419492; called by muse, mutect2, varscan2
- FAM89A | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 62/253 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs767532073, COSV100792581; called by muse, mutect2, varscan2
- FAM90A1 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 197/854 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs759052041, COSV56710439; called by muse, mutect2, varscan2
- FAM9C | c.329+2T>C p.X110_splice | Splice Site (SNP) | VAF 16/81 reads (20%) | catalogued as COSV61775796; called by muse, mutect2, varscan2
- FASN | c.4997G>A p.R1666H | Missense Mutation (SNP) | VAF 180/517 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs571435935; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASTKD3 | c.428del p.K143Rfs*36 | Frame Shift Del (DEL) | VAF 57/256 reads (22%) | catalogued as rs773607911, COSV52947201; called by mutect2, pindel, varscan2
- FAT2 | c.2375T>C p.V792A | Missense Mutation (SNP) | VAF 46/389 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs1488362415; called by muse, mutect2, varscan2
- FAT3 | c.9322G>A p.G3108R | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761440770, COSV53106053, COSV53169687; called by muse, mutect2, varscan2
- FAT4 | c.8213T>C p.V2738A | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.087); catalogued as COSV100628652; called by muse, mutect2
- FBXL13 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.344); catalogued as COSV100502173; called by muse, mutect2, varscan2
- FBXL3 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 101/394 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.196); catalogued as COSV62918669; called by muse, mutect2, varscan2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 46/156 reads (29%) | catalogued as rs772635228; called by mutect2, varscan2
- FER1L5 | c.2647C>T p.R883W (on ENST00000623019; = p.R888W on NM_001293083.2) | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs1251119530; called by muse, mutect2
- FERMT3 | c.1557+1G>A p.X519_splice (on ENST00000279227 / NM_178443.3; = p.X515_splice on NM_031471.6 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 91/366 reads (25%) | catalogued as rs1395478959; called by muse, mutect2, varscan2
- FERMT3 | c.1930C>T p.R644W (on ENST00000279227 / NM_178443.3; = p.R640W on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/712 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886043481, COSV54174076, COSV54176018; ClinVar: uncertain significance; called by mutect2, varscan2
- FGF2 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 66/299 reads (22%) | catalogued as rs781084194; called by muse, mutect2, varscan2
- FGF3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 70/304 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782801923; called by muse, mutect2, varscan2
- FGR | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1390856692; called by muse, mutect2, varscan2
- FHOD1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 78/230 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1410298332, COSV50760037; called by muse, mutect2, varscan2
- FHOD1 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 81/277 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs752830654; called by muse, mutect2, varscan2
- FHOD3 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs769863952, COSV57176444; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 25/129 reads (19%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FICD | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs1270108664, COSV99934608; called by muse, mutect2, varscan2
- FICD | c.1012C>T p.L338F | Missense Mutation (SNP) | VAF 93/351 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs367988876; called by muse, mutect2, varscan2
- FIGNL1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs146011869; called by muse, mutect2, varscan2
- FKBP4 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs142464168; called by muse, mutect2, varscan2
- FLNC | c.7697T>C p.M2566T | Missense Mutation (SNP) | VAF 156/564 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.113); catalogued as rs1421296226; called by muse, mutect2, varscan2
- FOXB2 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 70/280 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65023106; called by muse, mutect2, varscan2
- FOXD4L1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 264/1010 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as rs768067683; called by muse, mutect2, varscan2
- FOXO4 | c.1203dup p.L402Afs*6 | Frame Shift Ins (INS) | VAF 67/294 reads (23%) | catalogued as rs754124740; called by mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 35/135 reads (26%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMPD1 | c.4472G>A p.R1491H | Missense Mutation (SNP) | VAF 67/263 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs780248862, COSV66703083; called by muse, mutect2, varscan2
- FSIP2 | c.12590C>T p.T4197I | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.711); catalogued as rs1044975316; called by muse, mutect2, varscan2
- FST | c.315del p.K105Nfs*4 | Frame Shift Del (DEL) | VAF 60/326 reads (18%) | catalogued as rs1561296831; called by mutect2, pindel, varscan2
- FSTL4 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761186958, COSV54777832; called by muse, mutect2
- FYCO1 | c.584del p.P195Lfs*7 | Frame Shift Del (DEL) | VAF 49/176 reads (28%) | catalogued as rs1217916294; called by mutect2, pindel, varscan2
- GALNT8 | c.1169T>C p.L390P | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52895392; called by muse, mutect2, varscan2
- GALR1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 40/416 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV55318099; called by muse, mutect2
- GATA3 | c.708del p.S237Afs*28 | Frame Shift Del (DEL) | VAF 66/257 reads (26%) | catalogued as rs771019738, COSV60522496; called by mutect2, pindel, varscan2
- GDF7 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs781520892; called by muse, mutect2, varscan2
- GFM2 | c.2020G>A p.V674M | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.097); catalogued as rs367960522; ClinVar: likely benign; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | catalogued as rs750227570; called by mutect2, varscan2
- GLIS1 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 118/527 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV100389849; called by muse, mutect2
- GNA14 | c.877+1G>T p.X293_splice | Splice Site (SNP) | VAF 16/95 reads (17%) | catalogued as rs766501518; called by mutect2, varscan2
- GOLGA3 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372097416; called by muse, mutect2, varscan2
- GOLGA5 | c.1220T>C p.V407A | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs1566955412; called by muse, mutect2, varscan2
- GOLGA6C | c.2036del p.P679Rfs*? | Frame Shift Del (DEL) | VAF 56/281 reads (20%) | catalogued as rs773221176, COSV100316303; called by mutect2, varscan2
- GOLIM4 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs773791480, COSV58328258; called by muse, mutect2, varscan2
- GOLPH3L | c.233dup p.I79Hfs*20 | Frame Shift Ins (INS) | VAF 29/94 reads (31%) | catalogued as rs748411305; called by mutect2, pindel, varscan2
- GOT1 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.067); catalogued as rs753494019; called by mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs370114090; called by mutect2, varscan2
- GPATCH3 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1049835908, COSV64651665; called by muse, mutect2, varscan2
- GPHN | c.2137C>T p.P713S (on ENST00000315266 / NM_001377519.1; = p.P746S on NM_020806.5) | Missense Mutation (SNP) | VAF 68/317 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59479237; called by muse, mutect2, varscan2
- GPR152 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 144/453 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs754807161, COSV56888046; called by muse, mutect2, varscan2
- GPR157 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs200216809, COSV66233167, COSV66233503; called by muse, mutect2, varscan2
- GPR183 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV63116828; called by muse, mutect2
- GPR65 | c.371del p.F124Sfs*2 | Frame Shift Del (DEL) | VAF 95/421 reads (23%) | catalogued as rs770829884; called by mutect2, varscan2
- GPR68 | c.316T>C p.Y106H | Missense Mutation (SNP) | VAF 46/474 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755019164; called by muse, mutect2, varscan2
- GPRASP1 | c.3532G>A p.A1178T | Missense Mutation (SNP) | VAF 63/420 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as rs1485238312, COSV64355369; called by muse, mutect2, varscan2
- GPRC5C | c.982G>A p.A328T (on ENST00000652232; = p.A283T on NM_018653.4) | Missense Mutation (SNP) | VAF 96/321 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.322); catalogued as rs200067788; called by muse, mutect2, varscan2
- GRID2 | c.2140C>T p.R714* | Nonsense Mutation (SNP) | VAF 22/97 reads (23%) | catalogued as COSV56265407; called by muse, mutect2, varscan2
- GRM1 | c.3149C>T p.A1050V | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs759211795, COSV51120192; called by muse, mutect2, varscan2
- GRM6 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 84/358 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as rs749148809, COSV51446318; called by muse, mutect2, varscan2
- GTF2B | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as rs769046476, COSV100980563; called by muse, mutect2, varscan2
- GTF3C1 | c.5541del p.E1848Rfs*33 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | catalogued as rs763161381; called by mutect2, pindel, varscan2
- GTF3C1 | c.3538dup p.E1180Gfs*17 | Frame Shift Ins (INS) | VAF 30/119 reads (25%) | catalogued as rs1375103432; called by mutect2, pindel, varscan2
- GTSE1 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as rs772546680, COSV101483263; called by muse, mutect2
- H2BW1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 115/437 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.36); catalogued as rs782183127, COSV54220471; called by muse, mutect2, varscan2
- HAND2 | c.283C>G p.P95A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs75152023; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HDHD3 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs148070774; called by muse, mutect2, varscan2
- HELZ2 | c.6616dup p.R2206Pfs*42 (on ENST00000467148 / NM_001037335.2; = p.R1637Pfs*42 on NM_033405.3) | Frame Shift Ins (INS) | VAF 29/158 reads (18%) | catalogued as rs745497383; called by mutect2, varscan2
- HEPACAM | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 64/471 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs751732183, COSV53430381; called by muse, mutect2, varscan2
- HERC2 | c.13601G>A p.R4534H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1332131786, COSV55306200; called by muse, mutect2, varscan2
- HGF | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 86/372 reads (23%) | catalogued as rs1303795573, COSV55946618, COSV55955205; called by muse, mutect2, varscan2
- HGF | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.215); catalogued as rs750282888, COSV55947263; called by muse, mutect2, varscan2
- HGFAC | c.1362del p.R455Gfs*19 | Frame Shift Del (DEL) | VAF 64/307 reads (21%) | catalogued as rs761929917; called by mutect2, pindel, varscan2
- HIRIP3 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs202044584, COSV54229298; called by muse, mutect2, varscan2
- HIVEP1 | c.4501A>G p.T1501A | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV65102536; called by muse, mutect2
- HLA-B | c.626dup p.T211Dfs*10 | Frame Shift Ins (INS) | VAF 75/199 reads (38%) | catalogued as rs748204482, COSV69520417; called by mutect2, pindel, varscan2
- HMCN1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs779304400, COSV54913266; called by muse, mutect2, varscan2
- HMMR | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as rs764564030, COSV62374059; called by muse, mutect2, varscan2
- HOOK2 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs1185105948; called by muse, mutect2
- HOOK3 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 37/112 reads (33%) | catalogued as rs1449147637; called by muse, mutect2, varscan2
- HOXB13 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 114/400 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs1466480316, COSV51704525; called by muse, mutect2, varscan2
- HOXC10 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.081); catalogued as COSV57725736; called by muse, mutect2
- HOXD8 | c.459G>T p.E153D | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV100497103; called by muse, mutect2, varscan2
- HSPA4 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs1468327018; called by muse, varscan2
- HSPBAP1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs976147325, COSV60242595; called by muse, mutect2, varscan2
- HTT | c.7207C>T p.P2403S | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61860571; called by muse, mutect2, varscan2
- HUWE1 | c.6484C>T p.R2162W | Missense Mutation (SNP) | VAF 97/392 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53333602, COSV53361602; called by muse, mutect2, varscan2
- HYDIN | c.15025G>A p.A5009T | Missense Mutation (SNP) | VAF 124/462 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs199657414, COSV66639103; called by muse, mutect2, varscan2
- IDNK | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs191026618; called by muse, mutect2, varscan2
- IFFO2 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.367); catalogued as rs989260585; called by muse, mutect2, varscan2
- IFNL3 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as rs201104473; called by muse, mutect2, varscan2
- IGF2BP1 | c.280T>C p.W94R | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as rs1239541424; called by muse, mutect2, varscan2
- IGHE | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 120/443 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs758760504; called by muse, mutect2, varscan2
- IGHV3-66 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 80/398 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.271); catalogued as rs782802220; called by muse, varscan2
- IKBKE | c.1042del p.R348Dfs*32 | Frame Shift Del (DEL) | VAF 28/208 reads (13%) | catalogued as COSV65625022; called by mutect2, pindel, varscan2
- IL16 | c.2492G>A p.R831Q (on ENST00000302987 / NM_172217.5; = p.R130Q on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs761019455; called by mutect2, varscan2
- IL1RAPL1 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV56285655; called by muse, mutect2, varscan2
- INSM1 | c.1109A>G p.H370R | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs928450184, COSV59605147; called by muse, mutect2, varscan2
- INSRR | c.2851A>G p.T951A | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.297); catalogued as COSV100947284; called by muse, varscan2
- INTS1 | c.6326G>A p.R2109H | Missense Mutation (SNP) | VAF 91/333 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV67177768; called by muse, mutect2, varscan2
- INTU | c.1772del p.L591Cfs*2 | Frame Shift Del (DEL) | VAF 65/302 reads (22%) | catalogued as COSV58874688; called by mutect2, pindel, varscan2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 100/464 reads (22%) | catalogued as rs780982673; called by mutect2, varscan2
- IRS4 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 144/573 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV64533917; called by muse, mutect2, varscan2
- JPH3 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99413816; called by muse, mutect2, varscan2
- JUP | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs373919544; called by muse, mutect2, varscan2
- JUP | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1555602080; called by muse, mutect2, varscan2
- KCNG1 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 54/106 reads (51%) | catalogued as rs1162689511, COSV65369582; called by muse, varscan2
- KCNH2 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV100060454; called by muse, mutect2, varscan2
- KCNH3 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57790414; called by muse, varscan2
- KCNH8 | c.570+1G>A p.X190_splice | Splice Site (SNP) | VAF 21/82 reads (26%) | catalogued as rs755303397, COSV60463215; called by muse, mutect2, varscan2
- KCNK13 | c.1171del p.V391Wfs*7 | Frame Shift Del (DEL) | VAF 37/162 reads (23%) | catalogued as rs766469179, COSV56415804; called by mutect2, pindel, varscan2
- KCNU1 | c.1212G>T p.A404= | Splice Region (SNP) | VAF 8/76 reads (11%) | catalogued as COSV101299289; called by mutect2, varscan2
- KDM2B | c.3379G>A p.V1127I | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1349703563; called by muse, mutect2, varscan2
- KDM5A | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 36/168 reads (21%) | catalogued as rs768653465, COSV66996680; called by muse, mutect2, varscan2
- KDM6B | c.1537del p.R513Afs*69 | Frame Shift Del (DEL) | VAF 62/226 reads (27%) | catalogued as rs747555402; called by mutect2, varscan2
- KIAA1217 | c.217del p.R73Efs*22 | Frame Shift Del (DEL) | VAF 31/159 reads (19%) | catalogued as COSV64601592, COSV64611067; called by mutect2, pindel, varscan2
- KIAA1614 | c.149del p.P50Qfs*15 | Frame Shift Del (DEL) | VAF 54/193 reads (28%) | catalogued as rs771572430; called by mutect2, pindel, varscan2
- KIAA1671 | c.4555C>T p.R1519W | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159068202; called by muse, mutect2, varscan2
- KIF11 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs762253167; called by muse, mutect2, varscan2
- KIF18B | c.2359G>A p.V787I (on ENST00000593135 / NM_001265577.2; = p.V799I on NM_001264573.2) | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs745510143, COSV59274132; called by muse, mutect2, varscan2
- KIF1B | c.5039G>A p.R1680Q (on ENST00000377086 / NM_001365952.1; = p.R1634Q on NM_015074.3) | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs775552504; called by muse, mutect2, varscan2
- KIF21A | c.2305del p.T769Qfs*5 (on ENST00000361418 / NM_001378440.1; = p.T756Qfs*5 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 29/134 reads (22%) | catalogued as rs1219032396; called by mutect2, pindel, varscan2
- KIF21B | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 106/382 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59767461; called by muse, mutect2, varscan2
- KIF25 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 95/377 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.326); catalogued as rs1029467968; called by muse, mutect2, varscan2
- KIF26A | c.4085del p.P1362Rfs*24 | Frame Shift Del (DEL) | VAF 23/216 reads (11%) | catalogued as rs776136395; called by mutect2, pindel, varscan2
- KIF26B | c.5620G>A p.V1874M | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750089358; called by muse, mutect2, varscan2
- KLHL29 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs771752047; called by muse, mutect2, varscan2
- KLHL32 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 139/559 reads (25%) | catalogued as rs989995139; called by muse, mutect2, varscan2
- KPRP | c.619del p.Q207Sfs*4 | Frame Shift Del (DEL) | VAF 99/424 reads (23%) | catalogued as rs1160391112; called by mutect2, pindel, varscan2
- KPTN | c.273del p.K92Sfs*22 | Frame Shift Del (DEL) | VAF 54/228 reads (24%) | catalogued as COSV99645797; called by mutect2, pindel, varscan2
- KRT13 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 103/406 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs767777473, COSV99877547; called by muse, mutect2, varscan2
- KRT27 | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1253506199; called by muse, mutect2, varscan2
- KRT6B | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 50/460 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764818442, COSV52885952; called by muse, mutect2, varscan2
- KRT78 | c.138del p.C47Afs*40 | Frame Shift Del (DEL) | VAF 24/115 reads (21%) | catalogued as rs751653006; called by mutect2, pindel, varscan2
- L1CAM | c.1546+7C>T | Splice Region (SNP) | VAF 181/785 reads (23%) | catalogued as rs905500191; called by muse, mutect2, varscan2
- L3MBTL4 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757230528, COSV53115908; called by muse, mutect2, varscan2
- LAMA2 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 101/445 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs779703997; called by muse, mutect2, varscan2
- LAMA3 | c.9083C>T p.T3028M (on ENST00000313654 / NM_198129.4; = p.T1419M on NM_000227.6) | Missense Mutation (SNP) | VAF 95/407 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs925512818; called by muse, mutect2, varscan2
- LAMB4 | c.4310G>A p.R1437H | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs765033972, COSV52732357; called by muse, mutect2, varscan2
- LAMB4 | c.26del p.L9Cfs*43 | Frame Shift Del (DEL) | VAF 44/168 reads (26%) | catalogued as rs747409331; called by mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LEFTY1 | c.1037T>C p.M346T | Missense Mutation (SNP) | VAF 116/377 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs1351897006; called by muse, mutect2, varscan2
- LEUTX | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs754558994, COSV67691409, COSV67691429; called by muse, mutect2, varscan2
- LGR6 | c.2504G>A p.R835Q (on ENST00000367278 / NM_001017403.1; = p.R783Q on NM_021636.3) | Missense Mutation (SNP) | VAF 55/352 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1322470874, COSV99708011; called by muse, mutect2, varscan2
- LHX1 | c.1194dup p.E399Rfs*65 | Frame Shift Ins (INS) | VAF 30/149 reads (20%) | catalogued as rs775423572; called by mutect2, varscan2
- LILRA6 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 94/646 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1181339154; called by muse, mutect2, varscan2
- LINGO1 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 124/544 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.073); catalogued as COSV100796416; called by muse, mutect2, varscan2
- LIPE | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 104/416 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.038); catalogued as rs1314570280; called by muse, mutect2, varscan2
- LLGL2 | c.2758C>T p.R920C | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763257356, COSV51355848; called by muse, mutect2, varscan2
- LMTK2 | c.3865G>A p.E1289K | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs751509759, COSV52004999; called by muse, mutect2, varscan2
- LOXHD1 | c.5467C>T p.R1823W (on ENST00000642948; = p.R1761W on NM_144612.7) | Missense Mutation (SNP) | VAF 59/254 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759919888, COSV56061253; called by muse, mutect2, varscan2
- LOXL4 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs369940076; called by muse, mutect2, varscan2
- LRFN2 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.289); catalogued as rs968525802, COSV57828075; called by muse, mutect2, varscan2
- LRFN5 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs147658218; called by muse, mutect2, varscan2
- LRP1 | c.1797C>T p.D599= | Splice Region (SNP) | VAF 16/189 reads (8%) | catalogued as rs1290134523, COSV54506083; called by muse, mutect2
- LRP2 | c.4738G>A p.E1580K | Missense Mutation (SNP) | VAF 76/296 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761808473; called by muse, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC9 | c.745dup p.I249Nfs*5 | Frame Shift Ins (INS) | VAF 10/54 reads (19%) | catalogued as rs752960648; called by mutect2, varscan2
- LSR | c.634dup p.D212Gfs*20 | Frame Shift Ins (INS) | VAF 59/258 reads (23%) | catalogued as rs1350309519; called by pindel, varscan2
- LTN1 | c.2100del p.V701Sfs*5 | Frame Shift Del (DEL) | VAF 19/102 reads (19%) | catalogued as rs753955477; called by mutect2, pindel, varscan2
- LY75 | c.4565G>A p.R1522H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs758257235; called by muse, mutect2, varscan2
- MAD2L2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757723800; called by muse, mutect2, varscan2
- MAP2 | c.2485G>A p.A829T | Missense Mutation (SNP) | VAF 70/301 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV52302708; called by muse, mutect2, varscan2
- MAP2K1 | c.991A>G p.S331G | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV57235527; called by muse, mutect2, varscan2
- MAP2K7 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 72/324 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV67608070; called by muse, mutect2, varscan2
- MAP3K5 | c.2930G>C p.S977T | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); catalogued as COSV100753205, COSV62890617; called by muse, mutect2, varscan2
- MAP3K6 | c.2544dup p.F849Lfs*40 | Frame Shift Ins (INS) | VAF 48/188 reads (26%) | catalogued as rs34008139; called by mutect2, varscan2
- MAP3K9 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | catalogued as rs1299953155, COSV101173753; called by muse, mutect2
- MAP4K5 | c.226A>G p.N76D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1197481420; called by muse, mutect2, varscan2
- MAPKBP1 | c.4394G>A p.R1465Q (on ENST00000456763 / NM_001128608.2; = p.R1459Q on NM_014994.3) | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as rs755529786; called by muse, mutect2, varscan2
- MARCHF8 | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761710919; called by muse, mutect2, varscan2
- MBD5 | c.4436A>G p.D1479G | Missense Mutation (SNP) | VAF 87/466 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1559110260, COSV68698116; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MBP | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs141290653; called by muse, mutect2, varscan2
- MCF2L | c.3311G>A p.G1104D (on ENST00000375608; = p.G1072D on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/237 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV99995682; called by muse, mutect2, varscan2
- MCM9 | c.19A>G p.T7A | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0.007); catalogued as COSV60164812; called by muse, varscan2
- MCOLN1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 123/459 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369431026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MDH1B | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 74/314 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs369119966; called by muse, mutect2, varscan2
- MEFV | c.1027del p.Q343Rfs*25 | Frame Shift Del (DEL) | VAF 60/287 reads (21%) | catalogued as rs1167328352; called by mutect2, pindel, varscan2
- METTL17 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 68/271 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs139733527; called by muse, mutect2, varscan2
- MFSD3 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1329647905; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 29/61 reads (48%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MINK1 | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs1158259437, COSV53419980; called by muse, mutect2, varscan2
- MLIP | c.22A>G p.K8E | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as COSV51426119; called by muse, mutect2, varscan2
- MLXIPL | c.1488del p.A497Pfs*14 | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | catalogued as COSV57669632; called by mutect2, pindel, varscan2
- MMP14 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs768334466, COSV61289707; called by muse, mutect2, varscan2
- MMP20 | c.1241A>G p.Y414C | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.798); catalogued as rs747080892; called by muse, mutect2, varscan2
- MNDA | c.310dup p.I104Nfs*42 | Frame Shift Ins (INS) | VAF 18/85 reads (21%) | catalogued as rs751496931; called by mutect2, varscan2
- MON1A | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 103/349 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs765125214; called by muse, mutect2, varscan2
- MRTFB | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.015); catalogued as rs766778650, COSV100565478; called by muse, mutect2, varscan2
- MSH6 | c.3283C>T p.R1095C | Missense Mutation (SNP) | VAF 77/316 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs376243329; ClinVar: likely benign / uncertain significance / not provided; called by muse, varscan2
- MST1 | c.1436T>C p.F479S | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.793); catalogued as rs1240765341; called by muse, mutect2
- MTMR9 | c.584del p.N195Mfs*4 | Frame Shift Del (DEL) | VAF 18/90 reads (20%) | catalogued as rs767880823; called by mutect2, varscan2
- MTSS1 | c.459del p.R155Efs*34 | Frame Shift Del (DEL) | VAF 24/83 reads (29%) | catalogued as rs1563799887; called by mutect2, pindel, varscan2
- MX2 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 72/249 reads (29%) | catalogued as rs758619067, COSV58096964; called by muse, mutect2, varscan2
- MXRA5 | c.6530G>A p.R2177H | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs773254958, COSV54243733; called by muse, varscan2
- MXRA5 | c.4154C>T p.T1385M | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs755896826, COSV54231103; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 65/243 reads (27%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYH15 | c.5428G>T p.A1810S | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV99842190; called by muse, mutect2, varscan2
- MYH9 | c.2807C>T p.A936V | Missense Mutation (SNP) | VAF 126/538 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs773227499; called by muse, mutect2, varscan2
- MYO18B | c.1496G>A p.S499N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs1221481657; called by muse, mutect2
- MYO18B | c.5747A>C p.Q1916P | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59144272; called by muse, mutect2, varscan2
- MYOCD | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100590809; called by muse, mutect2, varscan2
- MYOCD | c.2348C>A p.A783D | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.462); catalogued as COSV58507175; called by mutect2, varscan2
- MYT1L | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1354027562; called by muse, mutect2, varscan2
- NAA10 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1557107264; called by muse, mutect2, varscan2
- NAGLU | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 172/654 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV99863920; called by muse, mutect2, varscan2
- NAIP | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs748373010, COSV52000909; called by muse, mutect2, varscan2
- NARS1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as rs200649043, COSV56877530; called by muse, mutect2, varscan2
- NAV2 | c.2712C>T p.S904= (on ENST00000396087 / NM_001244963.2; = p.S881= on NM_145117.5) | Splice Region (SNP) | VAF 15/96 reads (16%) | catalogued as rs138136292; called by muse, mutect2, varscan2
- NCAM2 | c.669G>T p.E223D | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99520917, COSV99525396; called by muse, mutect2, varscan2
- NCAPG | c.3011T>C p.L1004P | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs777357064; called by muse, mutect2, varscan2
- NCOA3 | c.1983_1985del p.S662del | In Frame Del (DEL) | VAF 54/231 reads (23%) | catalogued as rs772784655; called by pindel, varscan2
- NCOR2 | c.3952G>A p.V1318M | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.934); catalogued as rs201804156; called by muse, mutect2, varscan2
- NDUFV1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 133/494 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs375897089, CM138573; called by muse, mutect2, varscan2
- NEK6 | c.406T>C p.Y136H | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs868482996; called by muse, mutect2, varscan2
- NELFB | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 96/306 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753890137, COSV58025653; called by muse, mutect2, varscan2
- NELL1 | c.1022T>G p.V341G | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as COSV54299005; called by muse, mutect2, varscan2
- NFATC2IP | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs548471406, COSV104413715; called by muse, mutect2, varscan2
- NFATC4 | c.418del p.D140Tfs*63 | Frame Shift Del (DEL) | VAF 146/544 reads (27%) | catalogued as rs1253278380, COSV99148892; called by mutect2, varscan2
- NFKB1 | c.589C>T p.R197C (on ENST00000394820 / NM_001382627.1; = p.R198C on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as rs370846760; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs145147241; called by mutect2, varscan2
- NIPBL | c.8258G>A p.R2753H | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); catalogued as rs1360836577; called by muse, mutect2, varscan2
- NKX1-1 | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.817); catalogued as rs1396265942; called by muse, mutect2, varscan2
- NLGN2 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as rs748846516, COSV57211061; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- NLRP6 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56461374; called by muse, mutect2, varscan2
- NOD1 | c.1366G>A p.G456S | Missense Mutation (SNP) | VAF 126/505 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs748136700, COSV99767707; called by muse, mutect2, varscan2
- NOL4L | c.396del p.Y133Tfs*20 | Frame Shift Del (DEL) | VAF 52/204 reads (25%) | catalogued as rs751187638; called by mutect2, varscan2
- NOP53 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.571); catalogued as rs767092980, COSV55881674; called by muse, mutect2, varscan2
- NOTCH1 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 210/861 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as rs372771179; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH2 | c.3736G>T p.G1246* | Nonsense Mutation (SNP) | VAF 144/568 reads (25%) | catalogued as COSV99867943; called by muse, mutect2, varscan2
- NOTCH3 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 68/349 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs1393666105; called by muse, mutect2, varscan2
- NOTCH4 | c.3274G>A p.G1092S | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs761986491; called by muse, mutect2, varscan2
- NOTO | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs1416109456; called by muse, mutect2, varscan2
- NOX4 | c.1135+1G>A p.X379_splice | Splice Site (SNP) | VAF 20/108 reads (19%) | catalogued as rs201165492; called by muse, mutect2, varscan2
- NPAS3 | c.1841G>A p.R614H (on ENST00000356141 / NM_001164749.2; = p.R582H on NM_022123.3) | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.924); catalogued as rs745539855; called by muse, mutect2, varscan2
- NPAT | c.4109G>A p.R1370Q | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761839481, COSV104377230; called by muse, mutect2, varscan2
- NPAT | c.3185G>A p.R1062H | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1473195407, COSV53720981; called by muse, mutect2, varscan2
- NQO1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as rs568177350; called by muse, mutect2, varscan2
- NTF3 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 93/393 reads (24%) | catalogued as COSV58417989; called by muse, mutect2, varscan2
- NTN5 | c.970+1G>A p.X324_splice | Splice Site (SNP) | VAF 33/119 reads (28%) | catalogued as rs147095250, COSV54308546; called by muse, mutect2, varscan2
- NUP210 | c.3727G>A p.V1243M | Missense Mutation (SNP) | VAF 81/276 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327401524; called by muse, mutect2, varscan2
- NUP62 | c.845C>G p.T282S | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs149572563, COSV61310774; called by muse, mutect2, varscan2
- NUP85 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.056); catalogued as rs771947376, COSV55466551; called by muse, mutect2, varscan2
- NUP98 | c.5276T>C p.L1759P (on ENST00000359171 / NM_001365126.1; = p.L1742P on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 140/466 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs759772567, COSV51710535; called by muse, mutect2, varscan2
- NXNL1 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs1423687118; called by muse, mutect2, varscan2
- OAZ1 | c.477_479del p.L160del | In Frame Del (DEL) | VAF 76/296 reads (26%) | catalogued as rs1429838412; called by mutect2, pindel, varscan2
- OBSL1 | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs977533164; called by muse, mutect2, varscan2
- OPN1SW | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 93/393 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV50821610; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 66/359 reads (18%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR1Q1 | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs920987819; called by muse, mutect2, varscan2
- OR2AK2 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.125); catalogued as rs1448281390; called by muse, mutect2, varscan2
- OR2G2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as rs760919741, COSV60739255; called by muse, mutect2
- OR2M3 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs199968773, COSV71759103; called by muse, mutect2, varscan2
- OR2S2 | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV100558641; called by mutect2, varscan2
- OR4C16 | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 72/312 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs555112423, COSV58943406; called by muse, mutect2, varscan2
- OR4X1 | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 45/332 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as COSV60723350; called by muse, mutect2, varscan2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 50/286 reads (17%) | catalogued as rs1564877761; called by mutect2, pindel, varscan2
- OR51M1 | c.685T>C p.S229P | Missense Mutation (SNP) | VAF 122/481 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV60784314; called by muse, mutect2
- OR56B1 | c.878dup p.S294Ffs*15 | Frame Shift Ins (INS) | VAF 52/321 reads (16%) | catalogued as rs1564953116; called by mutect2, pindel, varscan2
- OR56B4 | c.546C>G p.H182Q | Missense Mutation (SNP) | VAF 184/685 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV100337654; called by muse, mutect2, varscan2
- OR5D18 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 131/520 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs149397041, COSV61736217; called by muse, mutect2, varscan2
- OR6X1 | c.844dup p.L282Pfs*10 | Frame Shift Ins (INS) | VAF 31/140 reads (22%) | catalogued as rs774084489; called by mutect2, pindel, varscan2
- OR6X1 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 91/360 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV60010459; called by muse, mutect2, varscan2
- OR7E24 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV101509700; called by muse, mutect2
- OSBPL1A | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs766711049; called by muse, mutect2, varscan2
- OVOL1 | c.433A>G p.R145G | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1335889968; called by muse, mutect2, varscan2
- P2RY6 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs778069030, COSV62936408; called by muse, mutect2, varscan2
- PABPC1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs777648449, COSV100589947; called by muse, varscan2
- PADI3 | c.832-1G>T p.X278_splice | Splice Site (SNP) | VAF 40/166 reads (24%) | catalogued as COSV99080984; called by muse, mutect2, varscan2
- PAPPA | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 99/457 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs767569306, COSV60280393; called by muse, mutect2, varscan2
- PAPPA | c.2570C>T p.T857M | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374066435; called by muse, mutect2, varscan2
- PAPPA | c.3316G>T p.D1106Y | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100075425; called by muse, mutect2
- PAX8 | c.1227del p.Y410Tfs*16 | Frame Shift Del (DEL) | VAF 31/281 reads (11%) | catalogued as COSV99049656; called by mutect2, pindel, varscan2
- PCDH1 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as rs1232738741, COSV54618744, COSV99747233; called by muse, mutect2, varscan2
- PCDH12 | c.2912A>G p.Q971R | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1047420178; called by muse, mutect2, varscan2
- PCDH12 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 131/561 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.351); catalogued as COSV51521222; called by muse, mutect2, varscan2
- PCDH17 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 130/552 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV64975021; called by muse, mutect2, varscan2
- PCDH19 | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 129/598 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as COSV55263965; called by muse, varscan2
- PCDH8 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV58812833; called by mutect2, varscan2
- PCDHA13 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 97/415 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.078); catalogued as rs1554173824, COSV56506589; called by muse, mutect2, varscan2
- PCDHB14 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 145/680 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); catalogued as rs782091970, COSV99506172; called by muse, mutect2, varscan2
- PCDHB15 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 195/904 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV51424178; called by muse, mutect2, varscan2
- PCDHB3 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 155/727 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as rs199816089, COSV99164164; called by muse, mutect2, varscan2
- PCDHGB2 | c.1523G>A p.S508N | Missense Mutation (SNP) | VAF 143/566 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.075); catalogued as COSV99533073; called by muse, mutect2, varscan2
- PCDHGB3 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV53923137; called by muse, mutect2, varscan2
- PCDHGB4 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 118/432 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs778705302; called by muse, mutect2, varscan2
- PCNT | c.349T>C p.C117R | Missense Mutation (SNP) | VAF 138/519 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs910342423, COSV64030442; called by muse, varscan2
- PDCL3 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs202185256; called by muse, mutect2, varscan2
- PDIA2 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 185/630 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs371790739; called by muse, mutect2, varscan2
- PDLIM1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs150307882; called by muse, mutect2, varscan2
- PDPR | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1186353564; called by muse, mutect2, varscan2
- PDZD4 | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs144109992; called by muse, mutect2
- PDZD7 | c.2692dup p.A898Gfs*63 | Frame Shift Ins (INS) | VAF 23/85 reads (27%) | catalogued as rs1177831852; called by mutect2, varscan2
- PER1 | c.3491G>A p.R1164Q | Missense Mutation (SNP) | VAF 86/319 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as rs776968404; called by muse, mutect2, varscan2
- PGAP3 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); catalogued as rs770428375; called by muse, mutect2, varscan2
- PGC | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV62678232; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 34/91 reads (37%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHC1 | c.2626C>T p.R876W | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs372044180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHF12 | c.2923G>A p.D975N | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs765509967, COSV60454552, COSV60456598; called by muse, mutect2, varscan2
- PHF12 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs755671414, COSV60453996, COSV60456565; called by muse, mutect2, varscan2
- PHF2 | c.2858del p.K953Rfs*7 | Frame Shift Del (DEL) | VAF 38/138 reads (28%) | catalogued as rs1252501615; called by mutect2, varscan2
- PHGR1 | c.109del p.H37Tfs*71 | Frame Shift Del (DEL) | VAF 14/73 reads (19%) | catalogued as rs1264440278; called by mutect2, pindel, varscan2
- PHLPP1 | c.4937G>A p.R1646Q | Missense Mutation (SNP) | VAF 79/285 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs769779242, COSV53031605; called by muse, mutect2, varscan2
- PHLPP2 | c.145A>T p.T49S | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as COSV62422747, COSV62426684; called by muse, mutect2, varscan2
- PIGN | c.2577-5del | Splice Region (DEL) | VAF 31/93 reads (33%) | catalogued as rs138671843; ClinVar: benign / likely benign; called by mutect2, varscan2
- PIK3AP1 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 77/328 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV59534913; called by muse, mutect2, varscan2
- PIK3C2B | c.3367G>A p.G1123S | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs780172936, COSV100916177; called by muse, mutect2, varscan2
- PITX1 | c.547_549del p.N183del | In Frame Del (DEL) | VAF 98/336 reads (29%) | catalogued as rs751855351; called by pindel, varscan2
- PJA1 | c.976C>T p.R326W (on ENST00000361478 / NM_145119.4; = p.R138W on NM_022368.5) | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs763394320; called by muse, mutect2, varscan2
- PKD1 | c.12008C>T p.A4003V (on ENST00000262304 / NM_001009944.3; = p.A4002V on NM_000296.4) | Missense Mutation (SNP) | VAF 77/776 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs754894660; called by muse, mutect2
- PKD1L1 | c.7429A>G p.T2477A | Missense Mutation (SNP) | VAF 49/381 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.193); catalogued as rs901619999; called by muse, mutect2, varscan2
- PKD1L1 | c.4739G>A p.R1580Q | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as rs750052718, COSV56960562; ClinVar: likely benign; called by muse, mutect2, varscan2
- PKD2 | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs1560592078; called by muse, varscan2
- PKN3 | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764868009, COSV99403587; called by muse, mutect2, varscan2
- PLA2G4C | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs771908409, COSV100843882; called by muse, mutect2, varscan2
- PLA2G4E | c.1657G>A p.G553S | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1166080441, COSV68150689; called by muse, mutect2, varscan2
- PLA2G4F | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs531064894; called by muse, mutect2, varscan2
- PLAC8 | c.64del p.Q22Rfs*37 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as rs1287583575; called by mutect2, pindel, varscan2
- PLCH1 | c.4925C>T p.T1642M (on ENST00000340059 / NM_001130960.2; = p.T1634M on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/334 reads (26%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs200586305; called by muse, mutect2, varscan2
- PLCXD1 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369600742, COSV67541540; called by muse, mutect2
- PLEC | c.1109C>T p.T370M (on ENST00000322810 / NM_201380.4; = p.T260M on NM_000445.5) | Missense Mutation (SNP) | VAF 214/745 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782174639; called by muse, mutect2, varscan2
- PLEKHA7 | c.2395G>T p.A799S | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63043642; called by muse, varscan2
- PLEKHG4 | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 62/650 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs199603402; called by muse, mutect2
- PLXNA1 | c.2314T>C p.Y772H | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs866130853; called by muse, mutect2, varscan2
- PLXNA1 | c.5243G>A p.R1748H | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778054825; called by muse, mutect2, varscan2
- PML | c.1682G>A p.S561N | Missense Mutation (SNP) | VAF 12/414 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99166597; called by muse, mutect2
- PNN | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV53766390; called by muse, mutect2
- POLR1A | c.4903G>A p.A1635T | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.264); catalogued as rs750443932; called by muse, mutect2, varscan2
- POLR1A | c.4103A>G p.N1368S | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs781468536, COSV99808047; called by muse, mutect2, varscan2
- POLRMT | c.1955del p.P652Rfs*19 | Frame Shift Del (DEL) | VAF 24/127 reads (19%) | catalogued as rs767274514; called by mutect2, pindel, varscan2
- POMGNT1 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 144/677 reads (21%) | PolyPhen benign (0.328); catalogued as rs770834730; ClinVar: uncertain significance; called by mutect2, varscan2
- POMT1 | c.1261del p.L421* | Frame Shift Del (DEL) | VAF 93/415 reads (22%) | catalogued as rs749018170; called by mutect2, pindel, varscan2
- PON2 | c.195del p.F65Lfs*5 | Frame Shift Del (DEL) | VAF 68/236 reads (29%) | catalogued as rs1201102139; called by mutect2, pindel, varscan2
- POTEE | c.1740C>A p.S580R | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV58242614; called by muse, mutect2, varscan2
- PPFIA4 | c.2420G>A p.R807Q (on ENST00000447715; = p.R808Q on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs566820389; called by muse, mutect2, varscan2
- PPP1R16B | c.138C>A p.H46Q | Missense Mutation (SNP) | VAF 110/456 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.105); catalogued as COSV100239972; called by mutect2, varscan2
- PPP2R2A | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs369862992, COSV60096160; called by muse, mutect2, varscan2
- PPRC1 | c.4382del p.P1461Hfs*79 | Frame Shift Del (DEL) | VAF 20/123 reads (16%) | catalogued as COSV53386648; called by mutect2, varscan2
- PRDM14 | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs1447674775, COSV52573189; called by muse, mutect2, varscan2
- PRDM15 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1331726697; called by mutect2, varscan2
- PRDM2 | c.4941del p.P1648Qfs*14 | Frame Shift Del (DEL) | VAF 24/139 reads (17%) | catalogued as COSV52450828; called by mutect2, pindel, varscan2
- PRICKLE2 | c.805C>T p.R269* (on ENST00000295902; = p.R213* on NM_198859.4) | Nonsense Mutation (SNP) | VAF 65/258 reads (25%) | catalogued as rs753970642, COSV55767918; called by muse, mutect2, varscan2
- PRKAR1A | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs1303569195, COSV100675287; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCSH | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 89/321 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.655); catalogued as rs150738221; called by muse, mutect2, varscan2
- PRPF4B | c.873del p.K291Nfs*8 | Frame Shift Del (DEL) | VAF 42/147 reads (29%) | catalogued as COSV61785191; called by mutect2, pindel, varscan2
- PRR23C | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1277613821; called by muse, mutect2, varscan2
- PRR36 | c.191del p.G64Afs*146 | Frame Shift Del (DEL) | VAF 77/245 reads (31%) | catalogued as rs1327235205; called by mutect2, pindel, varscan2
- PRRG3 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 70/342 reads (20%) | catalogued as rs774255267; called by muse, mutect2, varscan2
- PRSS53 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as rs1228843319, COSV54924443; called by muse, mutect2, varscan2
- PRSS8 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs1472961270, COSV54898586; called by muse, mutect2, varscan2
- PSMA7 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.801); catalogued as rs1215610166, COSV53380817; called by muse, mutect2, varscan2
- PSMB4 | c.783-3del | Splice Region (DEL) | VAF 26/135 reads (19%) | catalogued as rs776416627; called by mutect2, pindel, varscan2
- PTBP3 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.596); catalogued as rs1325998876; called by muse, mutect2, varscan2
- PTGIR | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs926892602; called by muse, mutect2, varscan2
- PTK2B | c.2709del p.E904Rfs*7 | Frame Shift Del (DEL) | VAF 57/214 reads (27%) | catalogued as rs869044240; called by mutect2, pindel, varscan2
- PTOV1 | c.871del p.E291Rfs*3 | Frame Shift Del (DEL) | VAF 36/172 reads (21%) | catalogued as COSV55588793; called by mutect2, varscan2
- PTPN13 | c.855del p.K285Nfs*45 | Frame Shift Del (DEL) | VAF 56/208 reads (27%) | catalogued as rs754278242; called by mutect2, varscan2
- PTPRD | c.3770C>T p.P1257L | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs748838568, COSV100644706, COSV61932157, COSV61984611; called by muse, mutect2, varscan2
- PTPRS | c.5755C>T p.R1919W | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290109580, COSV53616616; called by muse, mutect2, varscan2
- PTPRS | c.3094C>T p.R1032W | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.163); catalogued as rs766862256; called by muse, mutect2, varscan2
- PWWP2B | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.381); catalogued as rs756758285; called by muse, mutect2, varscan2
- PZP | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs779959248, COSV54354958, COSV54365221; called by muse, mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs754588466; called by mutect2, varscan2
- RAD51D | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 75/296 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs775268017, COSV50102776; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RANBP2 | c.3691C>T p.R1231C | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866098115, COSV51700379; called by muse, mutect2, varscan2
- RANBP3 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as rs770419454, COSV50381350; called by muse, mutect2, varscan2
- RAP1GAP | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs777201880, COSV99266249; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1715del p.T572Rfs*32 | Frame Shift Del (DEL) | VAF 43/165 reads (26%) | catalogued as COSV99623523; called by mutect2, pindel, varscan2
- RAPGEF3 | c.2446C>T p.P816S (on ENST00000389212; = p.P774S on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs763136670, COSV50220794; called by muse, mutect2, varscan2
- RAPGEF4 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.011); catalogued as rs1451485391, COSV99912065; called by muse, mutect2, varscan2
- RASA1 | c.1698+2T>G p.X566_splice | Splice Site (SNP) | VAF 35/160 reads (22%) | catalogued as COSV57205696; called by muse, mutect2, varscan2
- RBBP6 | c.2081C>T p.S694L | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs754328844, COSV60504293; called by muse, mutect2, varscan2
- RBM15B | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 71/253 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as rs1333647626; called by muse, mutect2, varscan2
- RELA | c.1459del p.H487Tfs*7 | Frame Shift Del (DEL) | VAF 20/180 reads (11%) | catalogued as COSV58014427; called by mutect2, pindel, varscan2
- RELB | c.1624C>A p.P542T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs1444124214; called by muse, mutect2, varscan2
- REN | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1459578412, COSV99689388; called by muse, mutect2, varscan2
- RFX1 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs772430581; called by muse, mutect2, varscan2
- RGS12 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs201540584, COSV60907325; called by muse, mutect2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 35/138 reads (25%) | catalogued as rs751982308; called by mutect2, varscan2
- RHBDF2 | c.2065G>A p.G689S | Missense Mutation (SNP) | VAF 30/556 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773584432; called by muse, mutect2
- RHEBL1 | c.328A>C p.T110P | Missense Mutation (SNP) | VAF 97/330 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.093); catalogued as COSV99987932; called by mutect2, varscan2
- RHOXF1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs1484612375, COSV54294908; called by muse, mutect2, varscan2
- RHOXF1 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as rs1246288348; called by muse, mutect2, varscan2
- RIBC1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1228774357; called by muse, mutect2, varscan2
- RIC1 | c.2272C>T p.R758C | Missense Mutation (SNP) | VAF 83/315 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs1286665062; called by muse, mutect2, varscan2
- RIN3 | c.2197G>A p.V733M | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775960520, COSV53655615; called by muse, mutect2, varscan2
- RIPOR1 | c.3193G>A p.A1065T (on ENST00000379312 / NM_001193522.2; = p.A1061T on NM_024519.4) | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772470305, COSV99243336; called by muse, varscan2
- RLIM | c.1377_1382del p.S475_S476del | In Frame Del (DEL) | VAF 65/343 reads (19%) | catalogued as rs764715887; called by mutect2, pindel, varscan2
- RMC1 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs760250700, COSV52572923; called by muse, mutect2, varscan2
- RNF216 | c.1298A>G p.N433S (on ENST00000425013 / NM_207116.3; = p.N490S on NM_207111.4) | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as rs778525036; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 47/159 reads (30%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF6 | c.1778dup p.L593Ffs*4 | Frame Shift Ins (INS) | VAF 70/284 reads (25%) | catalogued as rs1199638878; called by mutect2, varscan2
- ROBO2 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 81/316 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs1489562419, COSV59895738; called by muse, mutect2, varscan2
- ROBO2 | c.3233dup p.V1079Sfs*22 | Frame Shift Ins (INS) | VAF 44/266 reads (17%) | catalogued as rs745519558; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 40/76 reads (53%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA4 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 66/209 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as COSV53706933; called by muse, varscan2
- RPS6KA4 | c.2095C>T p.R699C | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV53706327; called by muse, mutect2
- RRAGB | c.475G>A p.E159K (on ENST00000262850 / NM_016656.4; = p.E131K on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs1418385559, COSV53329598; called by muse, mutect2
- RRP1B | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1295294853; called by muse, mutect2, varscan2
- RSPH14 | c.704T>C p.I235T | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.421); catalogued as rs764412189; called by muse, mutect2, varscan2
- RSPH6A | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 82/289 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as rs370604505; called by muse, mutect2, varscan2
- RYR2 | c.3256C>T p.R1086* | Nonsense Mutation (SNP) | VAF 25/111 reads (23%) | catalogued as rs371303783, COSV63704672; called by muse, mutect2, varscan2
- SALL3 | c.1281G>T p.K427N | Missense Mutation (SNP) | VAF 92/436 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101610108; called by mutect2, varscan2
- SAMD11 | c.653G>A p.S218N | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1308078794; called by muse, mutect2, varscan2
- SAMD4B | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as rs199609404; called by muse, mutect2, varscan2
- SART1 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs746052994; called by muse, mutect2, varscan2
- SBF1 | c.4973G>A p.R1658H | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs550773035, COSV100817967; called by muse, mutect2, varscan2
- SCARB1 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 21/672 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); catalogued as rs1378699597; called by muse, mutect2
- SCN7A | c.3656G>A p.R1219H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs201961641; called by muse, mutect2, varscan2
- SCNN1D | c.676G>A p.V226M (on ENST00000338555; = p.V390M on NM_001130413.4) | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.903); catalogued as rs745884849; called by muse, mutect2, varscan2
- SCUBE1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs751516631, COSV62611060, COSV62615530; called by muse, mutect2, varscan2
- SCUBE1 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757589620, COSV51810674; called by muse, mutect2, varscan2
- SDSL | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775169698; called by muse, mutect2, varscan2
- SEC14L2 | c.1126_1128del p.K376del | In Frame Del (DEL) | VAF 37/144 reads (26%) | catalogued as rs756706654; called by pindel, varscan2
- SEMA4A | c.364-1G>A p.X122_splice | Splice Site (SNP) | VAF 102/357 reads (29%) | catalogued as COSV61772896; called by mutect2, varscan2
- SERGEF | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.119); catalogued as rs1200064034; called by muse, mutect2, varscan2
- SERPINE3 | c.808del p.L270* | Frame Shift Del (DEL) | VAF 40/166 reads (24%) | catalogued as rs753981280; called by mutect2, varscan2
- SERTAD1 | c.491G>A p.C164Y | Missense Mutation (SNP) | VAF 105/385 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs148598399; called by muse, mutect2, varscan2
- SETD1A | c.1178del p.P393Lfs*104 | Frame Shift Del (DEL) | VAF 16/185 reads (9%) | catalogued as COSV52689654; called by mutect2, pindel
- SEZ6 | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100253646; called by muse, mutect2
- SGCG | c.161C>A p.T54K | Missense Mutation (SNP) | VAF 112/421 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs886043940; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGTA | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as rs138653817; called by muse, mutect2, varscan2
- SH2B2 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782579624; called by muse, mutect2, varscan2
- SH2D4B | c.988+2T>C p.X330_splice (on ENST00000646907; = p.X329_splice on NM_207372.2) | Splice Site (SNP) | VAF 23/147 reads (16%) | catalogued as rs758321542; called by muse, mutect2, varscan2
- SH3BP1 | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); catalogued as rs768349095; called by muse, mutect2, varscan2
- SH3BP5L | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV63538973; called by muse, mutect2, varscan2
- SH3PXD2B | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 149/527 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as rs745393171; called by muse, mutect2, varscan2
- SHANK2 | c.5298del p.S1767Rfs*32 | Frame Shift Del (DEL) | VAF 66/277 reads (24%) | catalogued as COSV53615556; called by mutect2, pindel, varscan2
- SHCBP1L | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV62356872; called by muse, mutect2, varscan2
- SHISAL1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs376878869; called by muse, varscan2
- SHQ1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs529764235, COSV57763786; called by muse, mutect2, varscan2
- SI | c.3715G>A p.V1239I | Missense Mutation (SNP) | VAF 93/392 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52281798; called by muse, mutect2, varscan2
- SIGLEC15 | c.112+1G>T p.X38_splice | Splice Site (SNP) | VAF 21/109 reads (19%) | catalogued as COSV101248869; called by muse, mutect2, varscan2
- SIK3 | c.2824C>T p.R942W (on ENST00000445177 / NM_001366686.2; = p.R900W on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs767005637, COSV99408808; called by muse, mutect2, varscan2
- SIM1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 81/283 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53488910; called by muse, mutect2, varscan2
- SIPA1L2 | c.3159del p.C1054Afs*194 | Frame Shift Del (DEL) | VAF 17/166 reads (10%) | catalogued as rs1366695849; called by mutect2, pindel, varscan2
- SIX2 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 132/561 reads (24%) | catalogued as rs11540435, COSV57391420; called by muse, mutect2, varscan2
- SKOR2 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 87/296 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as rs1321562547; called by muse, mutect2, varscan2
- SLAMF6 | c.839C>T p.T280M (on ENST00000368057 / NM_001184714.2; = p.T279M on NM_052931.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as rs765972398; called by muse, mutect2, varscan2
- SLC11A1 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs747063589; called by muse, mutect2, varscan2
- SLC1A5 | c.752A>G p.E251G | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs530038611; called by muse, mutect2
- SLC22A31 | c.711G>A p.R237= | Splice Region (SNP) | VAF 17/116 reads (15%) | catalogued as rs894777592; called by muse, varscan2
- SLC25A29 | c.661G>A p.G221R (on ENST00000359232 / NM_001039355.3; = p.G155R on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/369 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as rs1306459764; called by muse, mutect2, varscan2
- SLC28A1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 85/407 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs113577701; called by muse, mutect2, varscan2
- SLC2A10 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 133/577 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768203290, COSV63714620; called by muse, mutect2, varscan2
- SLC37A4 | c.458C>A p.P153H | Missense Mutation (SNP) | VAF 122/415 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM002022; called by muse, mutect2, varscan2
- SLC43A2 | c.719T>C p.M240T | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.065); catalogued as rs1450101392; called by muse, mutect2, varscan2
- SLC46A1 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 82/369 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555590836; called by muse, mutect2, varscan2
- SLC5A9 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs140121983; called by muse, mutect2, varscan2
- SLC8B1 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as rs375640801; called by muse, mutect2, varscan2
- SLCO6A1 | c.510del p.V171* | Frame Shift Del (DEL) | VAF 42/174 reads (24%) | catalogued as rs1561496021; called by mutect2, varscan2
- SMARCAD1 | c.2303dup p.N768Kfs*28 | Frame Shift Ins (INS) | VAF 44/217 reads (20%) | catalogued as rs750056186; called by mutect2, varscan2
- SMCO3 | c.589A>G p.K197E | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs567614549; called by muse, mutect2, varscan2
- SNRPN | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV57593843, COSV57596019; called by muse, mutect2, varscan2
- SNX33 | c.1299del p.C435Afs*62 | Frame Shift Del (DEL) | VAF 27/111 reads (24%) | catalogued as rs747082791; called by mutect2, pindel, varscan2
- SOCS7 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.999); catalogued as rs372829995; called by muse, varscan2
- SOGA3 | c.722del p.G241Afs*133 | Frame Shift Del (DEL) | VAF 70/244 reads (29%) | catalogued as rs778091058, COSV100846885; called by mutect2, pindel, varscan2
- SOX2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 139/471 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.305); catalogued as COSV57620872, COSV57621036; called by muse, mutect2, varscan2
- SOX9 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 69/300 reads (23%) | catalogued as COSV55423365; called by muse, mutect2, varscan2
- SP5 | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs757675219; called by muse, mutect2, varscan2
- SPATA31A1 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 111/819 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.975); catalogued as rs1389108239; called by muse, mutect2, varscan2
- SPEG | c.6697del p.Q2233Rfs*6 | Frame Shift Del (DEL) | VAF 78/272 reads (29%) | catalogued as rs752907815; called by mutect2, varscan2
- SPIN2A | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 90/539 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767177597; called by muse, mutect2, varscan2
- SQSTM1 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 124/419 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as rs763767102; called by muse, mutect2, varscan2
2,225 further variants in this file (1,210 protein-altering or splice-affecting, 611 silent, 404 other) are not listed here.
